Gene-level copy-number profile of tumor specimen TCGA-A6-2675-01A from TCGA case TCGA-A6-2675, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 78.9 years (28,813 days).
Specimen TCGA-A6-2675-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.5f36d619-2676-4d0c-ad6f-f61d582bb418.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-2675-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d3a64d55-0335-40d5-913f-c7b436735ca6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,422; copy number 2: 5,997; copy number 3: 29,553; copy number 4: 16,727; copy number 5: 3,267; copy number 6: 2,083; copy number 7: 83; copy number 8: 145; copy number 9: 203; copy number 10: 116; copy number 11: 109; copy number 12: 50; copy number 13: 38; copy number 15: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-2675-01A-02D-1717-01): tumor purity 0.42, ploidy 3.31, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 771 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:37,962,990–43,674,591, 147 genes, copy number 10–11 (broad region; genes not listed).
- chr20:8,831,186–9,530,524, 7 genes, copy number 9: RNU105B, AL445567.1, AL445567.2, Metazoa_SRP, PLCB4, LAMP5-AS1, LAMP5.
- chr20:9,562,941–9,577,689, 2 genes, copy number 9: AL353612.2, AL353612.1.
- chr20:12,865,202–13,169,103, 6 genes, copy number 8: LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1.
- chr20:15,280,764–15,985,876, 4 genes, copy number 7 (within-gene range 6–7): RNA5SP475, AL121584.1, ENSAP1, AL079338.1.
- chr20:17,693,672–20,360,703, 60 genes, copy number 8 (within-gene range 6–8): BANF2, AL035045.1, RNU6-192P, SNX5, OVOL2, SNORD17, MGME1, PTMAP3, AL160411.1, RPL15P1, RNU7-137P, Y_RNA, KAT14, PET117, GGCTP2, RN7SL14P, RNU2-56P, AL049646.2, ZNF133, AL049646.1, RN7SKP74, ZNF133-AS1, LINC00851, DZANK1, GCNT1P1, RNA5SP476, POLR3F, MIR3192, RPL21P3, RBBP9, RPS19P1, SEC23B, SMIM26, AL121900.1, DTD1, RN7SL638P, RNU6ATAC34P, DUXAP7, DTD1-AS1, EEF1A1P34, LINC00652, LINC00653, SCP2D1-AS1, SCP2D1, AL135936.1, AL136090.2, SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1.
- chr20:25,139,652–46,089,962, 521 genes, copy number 7–15 (broad region; genes not listed).
- chr20:47,826,969–48,849,458, 24 genes, copy number 8 (within-gene range 6–8): RNU7-173P, SRMP1, RNA5SP486, RNU7-92P, AL357558.2, AL357558.1, AL357558.3, LINC01522, LINC01523, AL139351.2, AL139351.3, AL139351.1, AL136102.1, AL121888.2, AL121888.1, LINC00494, AL137078.1, AL137078.2, AL049541.1, AL049541.2, RNU7-144P, PREX1, AL035106.1, AL133342.1.

Autosomal genes at a single copy (total copy number 1): 1,422. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
